Somatic mutation profile of tumor specimen MMRF_1325_1_BM_CD138pos (aliquot MMRF_1325_1_BM_CD138pos_T1_KAS5U_L00682) from MMRF case MMRF_1325, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.9 years (21,512 days).
Specimen MMRF_1325_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e611b9f6-7b11-4cc9-a8ac-43267cd99fa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1325_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1325_1_PB_Whole_C2_KAS5U_L00691; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78e75e84-c697-44b0-a4d8-4e590283d05a

The open-access MAF lists 48 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 13, Silent 7, 5'UTR 4, Intron 3, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCORL1 | c.3238G>A p.A1080T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1191937890; called by muse, mutect2, varscan2
- CROCC | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100978105; called by muse, mutect2
- EHD1 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760138247; called by muse, mutect2, varscan2
- IGHV2-70 | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs775504623; called by muse, varscan2
- IGLV5-45 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs1187796483; called by muse, mutect2, varscan2
- KDM4E | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs782053839, COSV71678337; called by muse, mutect2, varscan2
- OR5I1 | c.881T>G p.L294W | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1319732256; called by muse, mutect2, varscan2
- TBX15 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV52874639; called by muse, mutect2, varscan2
- APP | c.1803A>T p.K601N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.554); called by muse, mutect2
- CFAP47 | c.732A>C p.L244F | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); called by muse, mutect2
- ESF1 | c.295A>C p.T99P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIA2 | c.901T>G p.Y301D | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- MAN2C1 | c.997T>A p.W333R | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDGA2 | c.2122A>G p.T708A (on ENST00000399232 / NM_001113498.2; = p.T410A on NM_182830.4) | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ODR4 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC12A3 | c.2302A>G p.N768D | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.097); called by muse, mutect2
- USP26 | c.2194T>G p.F732V | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZFYVE9 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- CYP2E1 | c.63C>A p.S21= | Silent (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs376111067; called by muse, varscan2
- IGLV3-1 | c.189G>T p.V63= | Silent (SNP) | VAF 53/61 reads (87%) | catalogued as rs61731686; called by muse, varscan2
- KDR | c.3933C>T p.S1311= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs774371518, COSV55763505; called by muse, mutect2, varscan2
- LACTBL1 | c.705C>T p.S235= (on ENST00000618559; = p.S280= on NM_001289974.2) | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- MUC2 | c.804C>T p.P268= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs540968644; called by muse, mutect2, varscan2
- SSMEM1 | c.633G>A p.A211= | Silent (SNP) | VAF 60/128 reads (47%) | catalogued as rs374890168, COSV52833115; called by muse, mutect2, varscan2
- AJUBA | c.-56C>T | 5'UTR (SNP) | VAF 5/57 reads (9%) | catalogued as rs1025130893; called by muse, mutect2
- C7orf65 | n.2797G>A | RNA (SNP) | VAF 37/67 reads (55%) | catalogued as rs1031480507; called by muse, mutect2, varscan2
- CCDC92 | c.-59-1437G>C | Intron (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- CMTM4 | c.*2410A>G | 3'UTR (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- DIRAS3 | c.*254A>G | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- DNAJC17 | c.*2398C>G | 3'UTR (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- EFCAB7 | c.*105A>C | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- ENAM | c.*807A>G | 3'UTR (SNP) | VAF 71/168 reads (42%) | called by muse, mutect2, varscan2
- JMJD4 | c.*506G>A | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs904342309; called by muse, mutect2, varscan2
- KCNA4 | c.*813C>T | 3'UTR (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- LPP | c.1240+1642A>G | Intron (SNP) | VAF 64/123 reads (52%) | called by muse, mutect2, varscan2
- MAGEC2 | c.-30C>G | 5'UTR (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- NR3C2 | c.*786dup | 3'UTR (INS) | VAF 34/65 reads (52%) | catalogued as rs1034794029; called by mutect2, varscan2
- PHF20 | c.*2714T>A | 3'UTR (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- PPM1L | c.*9091T>G | 3'UTR (SNP) | VAF 23/65 reads (35%) | catalogued as rs1012342381; called by muse, varscan2
- PTGER3 | c.*212C>T | 3'UTR (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- RAB2B | c.*881G>A | 3'UTR (SNP) | VAF 60/128 reads (47%) | catalogued as rs755946608, COSV101176632; called by muse, mutect2, varscan2
- RGL2 | c.-89C>A | 5'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- SERPINB5 | c.*25C>T | 3'UTR (SNP) | VAF 54/93 reads (58%) | called by muse, mutect2, varscan2
- SIAH2 | c.-26C>G | 5'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- SPHK1 | chr17:76384447 C>T | 5'Flank (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- TDGF1P3 | n.233A>T | RNA (SNP) | VAF 81/154 reads (53%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.6588+97A>T | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
